Gene-level copy-number profile of tumor specimen TCGA-09-1674-01A from TCGA case TCGA-09-1674, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 79.1 years (28,878 days).
Specimen TCGA-09-1674-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e33a75e9-bfad-4575-8b7f-46c7bdef6df2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-09-1674-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/615009b9-f7b8-405b-8ef5-6fe62ac1d529

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 459; copy number 2: 14,032; copy number 3: 20,110; copy number 4: 12,902; copy number 5: 6,995; copy number 6: 3,173; copy number 7: 1,681; copy number 8: 83; copy number 9: 9; copy number 10: 29; copy number 13: 1; copy number 14: 138; copy number 17: 111; copy number 19: 89.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-09-1674-01A-01D-0559-01): tumor purity 0.95, ploidy 3.5, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,141 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:24,040,835–25,338,213, 37 genes, copy number 7 (within-gene range 4–7): AL591178.1, MYOM3, MYOM3-AS1, IL22RA1, IFNLR1, LINC02800, GRHL3-AS1, GRHL3, STPG1, NIPAL3, RCAN3AS, RCAN3, NCMAP-DT, NCMAP, AL445686.1, Y_RNA, SRRM1, AL445648.1, CLIC4, RNU6-1208P, RUNX3, MIR6731, RUNX3-AS1, AL445471.1, MIR4425, LINC02793, AL050344.1, IFITM3P7, AL031432.1, SYF2, AL031432.4, AL031432.5, RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6.
- chr2:117,536,387–117,539,464, 1 gene, copy number 8: AC064856.1.
- chr3:168,858,659–169,038,416, 5 genes, copy number 9: RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr5:37,379,285–38,608,354, 20 genes, copy number 7 (within-gene range 5–7): WDR70, KCTD9P5, RNU6-1190P, RNU6-484P, GDNF-AS1, GDNF, LINC02117, AC008869.1, LINC02110, AC034226.1, LINC02119, AC010338.1, EGFLAM, EGFLAM-AS4, EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR.
- chr5:38,557,502–38,557,561, 1 gene, copy number 7: MIR3650.
- chr5:39,718,984–44,808,777, 88 genes, copy number 7–14 (within-gene range 1–14) (broad region; genes not listed).
- chr5:45,254,948–45,895,970, 4 genes, copy number 10–13: HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr6:47,729,827–50,913,256, 43 genes, copy number 7–9: AL356421.2, AL356421.1, OPN5, RNU1-105P, PTCHD4, AL353138.1, HNRNPA3P4, RBMXP1, FO393412.1, AL391538.1, AL022099.1, AL589994.1, AL589994.2, FO393413.1, RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P, RHAG, CRISP2, AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1, AL132799.1, AL360175.1, AL135908.1, TFAP2D, TFAP2B, RPS17P5, AL049693.1, FTH1P5.
- chr7:9,082,557–10,085,494, 10 genes, copy number 7: AC004852.2, AC004852.1, AC004852.3, GAPDHP68, AC060834.2, PER3P1, AC060834.1, AC006363.1, AC010991.1, AC004936.1.
- chr12:66,767–62,279,150, 1,596 genes, copy number 7–10 (within-gene range 3–10) (broad region; genes not listed).
- chr19:35,040,506–37,218,153, 136 genes, copy number 14 (broad region; genes not listed).
- chr19:39,125,770–41,027,720, 111 genes, copy number 17 (broad region; genes not listed).
- chr19:42,397,128–42,652,355, 1 gene, copy number 19 (within-gene range 3–19): LIPE-AS1.
- chr19:42,428,278–44,305,046, 88 genes, copy number 19 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 162. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
